TCGA case TCGA-LA-A446 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Candler. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/12b44011-90c0-4a70-8ea4-a216ec0c0860

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 68 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.3; Tissue or organ of origin: Lower lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 69.0 years (25,199 days); Year of diagnosis: 2012; AJCC staging edition: 7th; AJCC pathologic T: T1b; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IA; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 401 days (1.1 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (3 entries)
- Days to follow up: 36 days; Disease response: Tumor Free.
- Days to follow up: 401 days (1.1 years); Disease response: Tumor Free.
- ECOG performance status: 0; Timepoint: Preoperative.

Other clinical attributes
- FEV1/FVC after bronchodilator (%): 62; FEV1/FVC before bronchodilator (%): 61; FEV1 after bronchodilator (% of reference): 92; FEV1 before bronchodilator (% of reference): 87.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 26; Tobacco smoking onset year: 1961.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-LA-A446-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 160 mg.
  Slide TCGA-LA-A446-01A-02-TSB: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 2; Percent stromal cells: 23; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 6; Percent neutrophil infiltration: 2.
- Sample TCGA-LA-A446-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-LA-A446-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Tumor status: Tumor free; Tobacco smoking history indicator: 2; Anatomic organ subdivision: R-Lower; Location lung parenchyma: Central Lung; KRAS gene analysis indicator: No; EGFR mutation status: No; Eml4 alk translocation status: No; Pulmonary function test indicator: Yes; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form: Lost to follow-up: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; New tumor event surgery: No; Tumor status: Tumor free; New tumor event surgery met: No; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 401 days; disease-specific survival: no event (censored), 401 days; disease-free interval: no event (censored), 401 days; progression-free interval: no event (censored), 401 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-LA-A446-01A-21D-A256-01): tumor purity 0.41, ploidy 3.23, whole-genome doublings 1.
